Surgical pathology report (de-identified scan), TCGA case TCGA-77-7463, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-7463-01A (Primary Tumor).

[REDACTED]

LEFT UPPER LOBECTOMY

Clinical Details:

FNA: Squamous cell carcinoma.

Macroscopy:

The specimen weighs 180 g and comprises a lobe of lung with appearances in keeping with left upper lobe. Within the superior lingular segment there is a tumour nodule measuring 30 x 28 x 25 mm. It is situated at a distance of 25 mm from the bronchial resection margin. The tumour has caused puckering of the overlying pleura. No pleural surface involvement is seen macroscopically. Inferior to this nodule, at a distance of 20 mm, there is a hard circumscribed fibrous nodule showing central caseation, measuring 14 mm in maximum diameter. Within the anterior segment there is a subpleural dark grey nodule measuring 6 mm in maximum diameter. The lung parenchyma otherwise appears normal. [A, bronchial resection margin to lingular segment; B, bronchial resection margin to anterior and apico-posterior segments; C, lymph nodes at resection margin; D, small subpleural nodule anterior segment; E, apex; F, anterior segment; G, nodule lingular segment; H-K, RS of tumour including pleura in each section (note: an endobronchial origin is not identified macroscopically)]. [REDACTED]

Microscopy:

Sections show a moderately differentiated squamous cell carcinoma which abuts but does not directly invade the pleura. However there is lymphatic permeation which does involve pleural lymphatics. No vascular invasion is identified. Peribronchial lymph nodes show no evidence of malignancy. The subpleural nodule in the anterior segment is shown to represent a silicotic nodule. The larger nodule in the lingular segment has a similar histological appearance but shows extensive central necrosis. Special stains will be performed to exclude superimposed infection.

Conclusion:

Left upper lobectomy:

Moderately differentiated squamous cell carcinoma, 30 mm in diameter.

Lymphatic invasion present, involving pleura.

No vascular invasion is seen

No lymph node metastasis present.

Pathological stage T2 N0.

T-28000 M-80703 P1-03000

[REDACTED]
Anatomical Pathologist

Copies:

Lung cancer registry
[REDACTED]

Further report:

[REDACTED] stains show no evidence of infective organisms.

[REDACTED]
Anatomical Pathologist

Source: NCI Genomic Data Commons file b4c8f8ef-5659-4ab4-b9b7-dc87584a2e0d (TCGA-77-7463.FD316526-B68E-491A-9E97-BF4D2146E977.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).